Somatic mutation profile of tumor specimen TCGA-23-1124-01A (aliquot TCGA-23-1124-01A-01W-0486-08) from TCGA case TCGA-23-1124, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.0 years (23,005 days).
Specimen TCGA-23-1124-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 552fdef6-a8e6-4ec9-8161-1e827f95dda6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1124-10A (Blood Derived Normal), aliquot TCGA-23-1124-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36ccc82a-2047-4089-ab08-821392e1f4d3

The open-access MAF lists 154 somatic variants for this specimen: 122 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 27, Splice Site 3, Frame Shift Del 3, Intron 2, 3'Flank 1, 3'UTR 1, In Frame Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 86/120 reads (72%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS6 | c.2509G>C p.D837H | Missense Mutation (SNP) | VAF 98/133 reads (74%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV66861542; called by muse, mutect2, varscan2
- ADGRV1 | c.7271G>A p.R2424K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.067); catalogued as COSV67988951; called by muse, mutect2, varscan2
- AGBL2 | c.2574G>C p.K858N | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV54093423; called by muse, mutect2, varscan2
- AKAP13 | c.5237G>T p.S1746I (on ENST00000394518 / NM_007200.5; = p.S1750I on NM_006738.6) | Missense Mutation (SNP) | VAF 94/870 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63462827; called by muse, mutect2, varscan2
- AKAP8L | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV101275699; called by muse, mutect2, varscan2
- AKAP9 | c.3486G>C p.Q1162H | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as COSV62350586, COSV62352748; called by muse, mutect2
- ARFIP1 | c.880C>G p.Q294E (on ENST00000353617 / NM_001287432.1; = p.Q262E on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61885277; called by muse, mutect2, varscan2
- ATAD2B | c.3605C>G p.S1202C | Missense Mutation (SNP) | VAF 75/392 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); catalogued as COSV53201567; called by muse, mutect2, varscan2
- BDKRB2 | c.1081A>T p.I361F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV60015631; called by muse, mutect2, varscan2
- BHMT | c.1016C>G p.T339S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV57154882; called by muse, mutect2, varscan2
- BSN | c.10671G>T p.E3557D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as COSV56521652; called by muse, mutect2, varscan2
- C9orf24 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as rs1165709635, COSV52624756; called by muse, mutect2, varscan2
- CA14 | c.257-1G>A p.X86_splice | Splice Site (SNP) | VAF 77/353 reads (22%) | catalogued as rs1348749294, COSV52529795; called by muse, mutect2, varscan2
- CCDC172 | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV60938452, COSV60939222; called by muse, varscan2
- CCDC183 | c.576G>C p.K192N | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV62013069; called by muse, mutect2, varscan2
- CCN3 | c.523C>G p.P175A | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52384361; called by muse, mutect2, varscan2
- CD163 | c.723A>T p.Q241H | Missense Mutation (SNP) | VAF 312/1801 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV63134455; called by muse, mutect2, varscan2
- CDCA7 | c.752A>G p.E251G (on ENST00000347703 / NM_145810.3; = p.E330G on NM_031942.5) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV60720760; called by muse, mutect2, varscan2
- CDH16 | c.1184C>G p.P395R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.02); catalogued as COSV55337728; called by muse, mutect2, varscan2
- CEACAM21 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51814867; called by muse, mutect2, varscan2
- CEP83 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100352584; called by muse, mutect2, varscan2
- CFAP43 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.638); catalogued as COSV53379123; called by muse, varscan2
- COL17A1 | c.2840T>A p.L947H | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.436); catalogued as COSV100792983; called by muse, mutect2
- CPB2 | c.1240A>C p.K414Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV51675579; called by muse, mutect2, varscan2
- CPS1 | c.2540G>C p.S847T | Missense Mutation (SNP) | VAF 150/275 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51802509, COSV51815034; called by muse, mutect2, varscan2
- CYP11A1 | c.1164C>A p.H388Q | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537187397, COSV51433001; called by muse, mutect2, varscan2
- CYP2C9 | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 201/845 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53250167, COSV99582961; called by muse, mutect2, varscan2
- DDX24 | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV58212928; called by muse, mutect2, varscan2
- DGKB | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs982542800, COSV51796521; called by muse, mutect2, varscan2
- DMXL2 | c.2891T>C p.L964P | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51849728; called by muse, mutect2, varscan2
- DNAH7 | c.3343A>G p.T1115A | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV100413482; called by muse, mutect2
- DSCAM | c.5069A>C p.D1690A | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV68030048; called by muse, mutect2, varscan2
- DYNC1I1 | c.1696A>C p.T566P | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV61464913; called by muse, mutect2, varscan2
- ENPP1 | c.2716G>C p.E906Q | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV62933708; called by muse, mutect2, varscan2
- EPHA5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99895346; called by muse, mutect2
- FAM155B | c.1244C>A p.P415H | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99368086, COSV99368099; called by muse, mutect2
- FAM187B | c.150C>A p.H50Q | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV61201479; called by muse, mutect2, varscan2
- FRZB | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54554793; called by muse, mutect2, varscan2
- GINS1 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 79/96 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52465748, COSV99319985; called by muse, mutect2, varscan2
- GLS2 | c.1650C>A p.D550E | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57665707; called by muse, mutect2, varscan2
- GPR149 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs747484911, COSV67668170; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2387C>G p.T796S | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.389); catalogued as COSV63100530; called by mutect2, varscan2
- HHEX | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV51106620; called by muse, mutect2, varscan2
- HTR5A | c.889T>G p.C297G | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55284646; called by muse, mutect2, varscan2
- HTT | c.6668G>A p.R2223Q | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs375059996; called by muse, mutect2
- IGHD | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV66655265; called by muse, mutect2, varscan2
- IKZF4 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.063); catalogued as COSV56267184, COSV56269605; called by muse, mutect2, varscan2
- IZUMO1R | c.363T>A p.N121K (on ENST00000440961; = p.N128K on NM_001199206.3) | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.373); catalogued as rs1201248218, COSV100126899, COSV60623053; called by muse, mutect2, varscan2
- KDELR3 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 132/225 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs752571011, COSV53248601; called by muse, mutect2, varscan2
- KDELR3 | c.581T>A p.F194Y | Missense Mutation (SNP) | VAF 127/222 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs756093412, COSV53248616; called by muse, mutect2, varscan2
- KDM7A | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV50092815; called by muse, mutect2, varscan2
- KLF12 | c.1003A>G p.K335E | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV66575410; called by muse, mutect2, varscan2
- KMT5C | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99726020; called by muse, mutect2
- LECT2 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV50847367; called by muse, mutect2, varscan2
- LPAR4 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70912945, COSV70913207, COSV70913547; called by muse, mutect2, varscan2
- LRPAP1 | c.730C>A p.Q244K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV56346600; called by muse, mutect2
- LRRC1 | c.344A>T p.N115I | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV63824442; called by muse, mutect2, varscan2
- MBTPS1 | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV58571490; called by muse, mutect2, varscan2
- MFSD11 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV60625537; called by muse, mutect2, varscan2
- MGAT1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 19/23 reads (83%) | PolyPhen probably damaging (1); catalogued as rs1184766082, COSV57133158; called by muse, mutect2, varscan2
- MKRN1 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV55437535; called by muse, mutect2, varscan2
- MLXIP | c.2495G>T p.W832L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59836437; called by muse, mutect2
- MMP10 | c.921del p.F308Lfs*20 | Frame Shift Del (DEL) | VAF 22/212 reads (10%) | catalogued as COSV104380172; called by mutect2, varscan2
- MOSPD1 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV66189412; called by muse, mutect2, varscan2
- MPI | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60397129; called by muse, mutect2, varscan2
- MYCBP2 | c.13407G>C p.M4469I (on ENST00000357337; = p.M4507I on NM_015057.5) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV62026818; called by muse, mutect2, varscan2
- MYH11 | c.2357T>C p.I786T | Missense Mutation (SNP) | VAF 165/510 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55558736; called by muse, mutect2, varscan2
- NAV3 | c.5875C>T p.R1959C (on ENST00000397909 / NM_001024383.2; = p.R1937C on NM_014903.6) | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs573838509, COSV57091466; called by muse, mutect2, varscan2
- NCAPD3 | c.4174+1G>T p.X1392_splice | Splice Site (SNP) | VAF 135/459 reads (29%) | catalogued as rs1319843949, COSV73187882; called by muse, mutect2, varscan2
- NSMCE3 | c.712A>T p.I238L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV99720438; called by muse, mutect2, varscan2
- NUTM2A | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758583691, COSV101095628; called by mutect2, varscan2
- NWD1 | c.722C>G p.T241S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60345236; called by muse, mutect2, varscan2
- OTOP2 | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58882491; called by muse, mutect2, varscan2
- PLA2G4F | c.2024G>C p.C675S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51827755; called by muse, mutect2, varscan2
- PLCB3 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1228790993, COSV54189979; called by muse, mutect2, varscan2
- PLCZ1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56855235; called by muse, mutect2, varscan2
- POGZ | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 174/408 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs748616193, COSV55038145; called by muse, mutect2, varscan2
- POU4F1 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV65884662; called by muse, mutect2, varscan2
- PPP3CC | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51501816; called by muse, mutect2
- PRAMEF12 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63215787; called by muse, mutect2, varscan2
- PRKCB | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV57787184; called by muse, mutect2, varscan2
- PROKR1 | c.995T>G p.M332R | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58138182; called by muse, mutect2, varscan2
- PSG8 | c.1277T>C p.I426T | Missense Mutation (SNP) | VAF 16/523 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV100125925; called by muse, mutect2
- PTPRF | c.2688C>G p.N896K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1186558185, COSV63446352; called by muse, mutect2, varscan2
- RBMX | c.1159G>C p.G387R | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.637); catalogued as COSV100284476, COSV57810129; called by muse, mutect2
- RPGRIP1L | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV50904667, COSV50909492; called by muse, mutect2, varscan2
- RXRB | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63399829; called by muse, mutect2, varscan2
- SDC1 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV54340427; called by muse, mutect2, varscan2
- SEC14L1 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs774609620, COSV66723273; called by muse, mutect2, varscan2
- SEC23B | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99357316; called by muse, mutect2
- SF3A1 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53169831; called by muse, mutect2, varscan2
- SLC38A11 | c.362T>A p.L121H (on ENST00000409149 / NM_001351539.1; = p.L99H on NM_173512.2) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58054658; called by muse, mutect2, varscan2
- SLC4A5 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374602113; called by muse, mutect2, varscan2
- SLC4A5 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as COSV61029737; called by muse, mutect2, varscan2
- SLC52A3 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV54078049; called by muse, mutect2, varscan2
- SLC6A3 | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54365744, COSV54365944; called by muse, mutect2, varscan2
- SPP1 | c.685C>A p.Q229K (on ENST00000395080 / NM_001040058.2; = p.Q215K on NM_000582.2) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV52952068; called by muse, mutect2, varscan2
- STYXL2 | c.2891G>A p.R964K | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs769537426, COSV54806907; called by muse, mutect2, varscan2
- SWAP70 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 88/309 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV59665035; called by muse, mutect2, varscan2
- TAS2R8 | c.437T>A p.L146H | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53689390; called by muse, mutect2, varscan2
- TIMMDC1 | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51787176; called by muse, mutect2, varscan2
- TLE6 | c.1361C>A p.P454H (on ENST00000246112 / NM_001143986.2; = p.P331H on NM_024760.3) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55736416, COSV55737080; called by muse, mutect2, varscan2
- TM7SF2 | c.598G>C p.G200R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54208126; called by muse, mutect2, varscan2
- TNS3 | c.850A>C p.K284Q | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV60793848; called by muse, mutect2, varscan2
- TRPV3 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 106/158 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.2); catalogued as rs758875463, COSV56792615; called by muse, mutect2, varscan2
- TTC3 | c.3361C>G p.H1121D | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV61292554; called by muse, mutect2, varscan2
- UACA | c.3881A>G p.D1294G | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1005420623, COSV59857224; called by muse, mutect2, varscan2
- UBA7 | c.1581C>A p.N527K | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV61092638; called by muse, mutect2, varscan2
- USP33 | c.2273C>G p.P758R | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62470142; called by muse, mutect2, varscan2
- WDR47 | c.1130+1G>A p.X377_splice | Splice Site (SNP) | VAF 32/227 reads (14%) | catalogued as COSV100728212; called by muse, mutect2, varscan2
- WIF1 | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV54133184; called by muse, mutect2, varscan2
- YES1 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 41/154 reads (27%) | catalogued as rs1354676545, COSV58848775; called by muse, mutect2, varscan2
- ZNF14 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055598017, COSV59850232; called by muse, mutect2, varscan2
- ZNF16 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 58/577 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52764451; called by muse, mutect2, varscan2
- ZNF326 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV61035735; called by muse, mutect2, varscan2
- ADCK2 | c.1798del p.G601Afs*63 | Frame Shift Del (DEL) | VAF 26/167 reads (16%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2472G>A p.M824I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.074); called by muse, mutect2
- IGLV1-44 | c.245T>A p.F82Y | Missense Mutation (SNP) | VAF 81/383 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.324); called by muse, varscan2
- KRT72 | c.396_407del p.N133_F136del | In Frame Del (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel, varscan2
- TRAV21 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.325); called by muse, mutect2
- XIRP2 | c.1894_1910del p.K632* (on ENST00000628543; = p.K807* on NM_152381.6) | Frame Shift Del (DEL) | VAF 55/143 reads (38%) | called by mutect2, pindel, varscan2
- ACP6 | c.330C>T p.Y110= | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as COSV65077333; called by muse, mutect2, varscan2
- AK9 | c.3498A>G p.E1166= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as COSV58144892; called by muse, mutect2, varscan2
- ATRX | c.5220A>C p.S1740= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100969847; called by muse, mutect2, varscan2
- FMNL2 | c.480C>T p.S160= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV56498253; called by muse, mutect2, varscan2
- GRIP1 | c.909C>A p.S303= | Silent (SNP) | VAF 83/145 reads (57%) | catalogued as COSV54030059; called by muse, mutect2, varscan2
- NIM1K | c.1011C>T p.F337= | Silent (SNP) | VAF 85/339 reads (25%) | catalogued as COSV58143066; called by muse, mutect2, varscan2
- NSMCE3 | c.711G>A p.R237= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99720439; called by muse, mutect2, varscan2
- OR11H4 | c.255C>T p.S85= | Silent (SNP) | VAF 59/295 reads (20%) | catalogued as COSV100197587, COSV59560507; called by muse, mutect2, varscan2
- OR51B2 | c.522T>G p.R174= | Silent (SNP) | VAF 55/246 reads (22%) | catalogued as COSV60915823, COSV60917071; called by muse, mutect2, varscan2
- OR52H1 | c.198C>G p.S66= (on ENST00000322653; = p.S72= on NM_001005289.1) | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as COSV59505658, COSV59506410; called by muse, mutect2, varscan2
- PALLD | c.2520C>T p.H840= (on ENST00000505667 / NM_001166108.2; = p.H823= on NM_016081.4) | Silent (SNP) | VAF 59/138 reads (43%) | catalogued as COSV54985111; called by muse, mutect2, varscan2
- PCDHGA1 | c.1911G>A p.A637= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs763255155, COSV65296062; called by muse, mutect2, varscan2
- PGF | c.282T>C p.C94= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV99462155; called by muse, mutect2, varscan2
- PLEKHO2 | c.1206C>A p.P402= | Silent (SNP) | VAF 41/51 reads (80%) | catalogued as COSV60262371, COSV60263337; called by muse, mutect2, varscan2
- POLM | c.192C>T p.S64= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs745946699, COSV54243124; called by muse, mutect2, varscan2
- RBPMS | c.72G>C p.R24= | Silent (SNP) | VAF 90/152 reads (59%) | catalogued as COSV55124616; called by muse, mutect2, varscan2
- SLC5A11 | c.816G>T p.P272= | Silent (SNP) | VAF 343/1069 reads (32%) | catalogued as COSV61742379; called by muse, mutect2, varscan2
- SMARCA4 | c.381T>C p.S127= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV100758024; called by muse, mutect2
- SMG8 | c.1596T>C p.L532= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV56286040; called by muse, mutect2, varscan2
- SYN2 | c.1254G>T p.L418= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV70285811; called by muse, mutect2, varscan2
- SYNM | c.3918A>G p.T1306= | Silent (SNP) | VAF 89/574 reads (16%) | catalogued as rs782591572, COSV50442568; called by muse, mutect2, varscan2
- TRIM55 | c.114G>A p.V38= | Silent (SNP) | VAF 100/691 reads (14%) | catalogued as COSV52547718; called by muse, mutect2, varscan2
- USP34 | c.4299C>T p.S1433= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as rs775616779, COSV68403025; called by muse, mutect2, varscan2
- VPS11 | c.753G>C p.R251= (on ENST00000620429; = p.R795= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- WWC1 | c.3186G>A p.Q1062= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV54653734; called by muse, mutect2, varscan2
- XCR1 | c.720C>T p.P240= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV58569903, COSV58571204; called by muse, mutect2, varscan2
- XKR9 | c.960T>C p.P320= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV68773143; called by muse, mutect2, varscan2
- LRRC23 | c.*164C>T | 3'UTR (SNP) | VAF 59/369 reads (16%) | catalogued as rs1174791083, COSV50391042; called by muse, mutect2, varscan2
- MASP1 | c.1303+5149G>A | Intron (SNP) | VAF 15/81 reads (19%) | catalogued as COSV56225117; called by muse, mutect2, varscan2
- RAP1GAP | c.-148-1748G>A | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as COSV51574332; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928644 T>G | 3'Flank (SNP) | VAF 12/22 reads (55%) | catalogued as COSV60484028, COSV60486986; called by muse, mutect2, varscan2
- SPATA8 | n.834T>C | RNA (SNP) | VAF 36/351 reads (10%) | catalogued as COSV60705051; called by muse, mutect2
